Somatic mutation profile of tumor specimen C3L-09973-01 (aliquot CPT0516480006) from CPTAC case C3L-09973, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.2 years (23,073 days).
Specimen C3L-09973-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13b98b88-ac33-4b95-930d-83b72ce8e94c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09973-31 (Blood Derived Normal), aliquot CPT0516540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13c95f17-237a-4d2e-a555-64ab40e3801a

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 41/296 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1H | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 72/505 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369630836; called by muse, mutect2, varscan2
- CDH1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55728790, COSV55740273; called by muse, mutect2
- CORO7 | c.2480T>G p.V827G | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52029619; called by muse, mutect2, varscan2
- ELOB | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs1478717435, COSV99241237; called by muse, mutect2
- EPHA3 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60717297; called by muse, varscan2
- KIFC3 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 42/614 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1346449990; called by muse, mutect2
- MFSD6 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 89/486 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs749919012, COSV55623981; called by muse, mutect2, varscan2
- MRPS14 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 55/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748241995; called by muse, mutect2, varscan2
- PROKR2 | c.1091A>G p.D364G | Missense Mutation (SNP) | VAF 75/418 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs766469410; called by muse, mutect2, varscan2
- PTPRN | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 33/662 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs370564509; called by muse, mutect2
- RYR2 | c.7234G>A p.G2412R | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550534270, COSV100772934, COSV63696306; ClinVar: uncertain significance; called by muse, mutect2
- TIAM1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs199941816, COSV54539115; called by muse, mutect2
- ADRB3 | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 41/668 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARFRP1 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 30/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CHST15 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 40/702 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- EIF4G2 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- FSCN1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 124/665 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GGA1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 119/472 reads (25%) | called by muse, varscan2
- MSC | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 50/698 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- MYOM3 | c.3609C>G p.D1203E | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.416); called by muse, mutect2
- ROBO2 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC17A6 | c.1402A>T p.T468S | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- SLC6A3 | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- VAV3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 43/612 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- AKR7L | c.528G>A p.R176= | Silent (SNP) | VAF 24/401 reads (6%) | called by muse, mutect2
- CDH23 | c.6465G>T p.S2155= | Silent (SNP) | VAF 38/364 reads (10%) | catalogued as COSV56470585; called by muse, mutect2, varscan2
- CFAP65 | c.4563C>T p.C1521= | Silent (SNP) | VAF 52/245 reads (21%) | called by muse, mutect2, varscan2
- FOXF1 | c.330C>T p.P110= | Silent (SNP) | VAF 26/782 reads (3%) | called by muse, mutect2
- GRM4 | c.255A>G p.G85= | Silent (SNP) | VAF 97/784 reads (12%) | called by muse, mutect2, varscan2
- OR4C3 | c.108G>A p.T36= | Silent (SNP) | VAF 69/355 reads (19%) | catalogued as rs78490540; called by muse, mutect2, varscan2
- TPO | c.2487C>T p.Y829= | Silent (SNP) | VAF 56/470 reads (12%) | catalogued as rs774085308, COSV100221133; called by muse, mutect2, varscan2
- ITGAX | c.430+57C>T | Intron (SNP) | VAF 70/506 reads (14%) | called by muse, varscan2
